Somatic mutation profile of tumor specimen 0DRXEK from CCDI case PBCHFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Leydig cell tumor, benign; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 8.4 years (3,080 days).
Specimen 0DRXEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9682cd66-b63e-470e-92e6-a39a84bc212c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXEV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e86637ae-bd16-44fe-af7b-f7b66e865d9c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LHCGR | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 134/1024 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121912532, CM950781, COSV54297049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 42/1232 reads (3%) | called by muse, mutect2
- ZNF837 | c.1086G>A p.P362= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs777300573; called by muse, mutect2, varscan2
